Somatic mutation profile of tumor specimen TARGET-30-PASPGB-01A (aliquot TARGET-30-PASPGB-01A-01D) from TARGET case TARGET-30-PASPGB, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 1.3 years (458 days).
Specimen TARGET-30-PASPGB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae01b229-2b6a-4e8c-b96c-424496d4bee2.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASPGB-10A (Blood Derived Normal), aliquot TARGET-30-PASPGB-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d1eb3e5b-1e79-47a0-948b-a2d6ca2a70fd

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPRC | c.1351C>T p.P451S | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.553); catalogued as COSV61411987; called by muse, mutect2, varscan2
- NF2 | c.*1846G>T | 3'UTR (SNP) | VAF 10/107 reads (9%) | called by muse, mutect2
